Somatic mutation profile of tumor specimen TCGA-B6-A0RV-01A (aliquot TCGA-B6-A0RV-01A-11D-A099-09) from TCGA case TCGA-B6-A0RV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 42.5 years (15,507 days).
Specimen TCGA-B6-A0RV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c85eee9-9f37-4ba5-8d4b-d148f63e4059.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0RV-10A (Blood Derived Normal), aliquot TCGA-B6-A0RV-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2395888e-d688-499d-8f42-ea17924d2a1f

The open-access MAF lists 46 somatic variants for this specimen: 30 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 15, Splice Site 3, Nonsense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC12 | c.1897G>A p.V633M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs753704696, COSV60915738; called by muse, mutect2, varscan2
- ABL1 | c.1086-1G>C p.X362_splice | Splice Site (SNP) | VAF 18/67 reads (27%) | catalogued as COSV59336000; called by muse, mutect2, varscan2
- AKAP9 | c.8464C>G p.L2822V (on ENST00000359028; = p.L2798V on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.477); catalogued as rs750034104, COSV62339320, COSV62351713; called by muse, mutect2, varscan2
- ALOX12 | c.795G>C p.E265D | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV52350825; called by muse, mutect2
- ANAPC7 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 66/326 reads (20%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV71443897; called by muse, mutect2, varscan2
- ARID2 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 35/123 reads (28%) | catalogued as rs146524163, COSV57605716; called by muse, mutect2, varscan2
- ATM | c.6096-1G>A p.X2032_splice | Splice Site (SNP) | VAF 31/118 reads (26%) | catalogued as COSV53734211, COSV53746377; called by muse, mutect2, varscan2
- CST5 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1257216384, COSV59014953; called by muse, mutect2, varscan2
- ELP5 | c.336G>C p.K112N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.187); catalogued as COSV59708935; called by muse, mutect2, varscan2
- GMDS | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as COSV66437956; called by muse, mutect2, varscan2
- GRIA1 | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.025); catalogued as rs1196248584, COSV53589729, COSV53612817; called by muse, mutect2, varscan2
- HIPK1 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.162); catalogued as COSV65784513, COSV65785903; called by mutect2, varscan2
- IFIH1 | c.2553G>C p.E851D | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV55128254; called by muse, mutect2, varscan2
- INTS8 | c.2510T>C p.I837T | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV58251975; called by muse, mutect2, varscan2
- JAGN1 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 29/124 reads (23%) | catalogued as COSV57062576; called by muse, mutect2, varscan2
- KCNQ2 | c.345C>G p.I115M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60436292; called by muse, mutect2, varscan2
- MAP2K4 | c.1086+1G>A p.X362_splice | Splice Site (SNP) | VAF 30/145 reads (21%) | catalogued as COSV62258858, COSV62261284; called by muse, mutect2, varscan2
- MRPS15 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as rs370868915; called by muse, mutect2, varscan2
- NEB | c.14905C>G p.H4969D | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.987); catalogued as COSV51434657; called by muse, mutect2, varscan2
- NELFCD | c.517G>A p.E173K (on ENST00000602795; = p.E155K on NM_198976.4) | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59747549; called by muse, mutect2, varscan2
- PTPN21 | c.231G>C p.W77C | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100162405; called by muse, mutect2
- SALL2 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.59); catalogued as rs999009122, COSV58104559; called by muse, mutect2, varscan2
- SEPTIN1 | c.214G>C p.D72H (on ENST00000321367; = p.D25H on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV58442877; called by muse, mutect2, varscan2
- SERPINB3 | c.1063T>A p.S355T | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs747263941, COSV99380112; called by muse, mutect2
- SWAP70 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV59665364; called by muse, mutect2, varscan2
- USP12 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs759422176, COSV56654994; called by muse, mutect2, varscan2
- VPS13B | c.6682G>C p.E2228Q | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV62149083, COSV62160379; called by muse, mutect2, varscan2
- VPS41 | c.1566G>C p.K522N | Missense Mutation (SNP) | VAF 123/344 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs1196651829, COSV59645682, COSV59650758; called by muse, mutect2, varscan2
- ZNF610 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58345435; called by muse, mutect2, varscan2
- MIB2 | c.1546G>C p.A516P | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); called by muse, mutect2
- ADCY2 | c.2745C>G p.L915= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV57884329; called by muse, mutect2, varscan2
- ADD1 | c.2184G>A p.L728= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV53271231; called by muse, mutect2, varscan2
- CACNA1G | c.4278C>T p.F1426= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as rs1442098848, COSV61720518; called by muse, mutect2, varscan2
- CDK1 | c.846G>A p.L282= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as rs756294007, COSV57349908; called by muse, mutect2, varscan2
- EXOC3 | c.9G>A p.E3= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV59267687; called by muse, mutect2, varscan2
- FAR1 | c.279C>T p.L93= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as rs1317517299, COSV61385513; called by muse, mutect2, varscan2
- FRMPD2 | c.3312C>G p.L1104= | Silent (SNP) | VAF 23/177 reads (13%) | catalogued as COSV59720305; called by muse, mutect2, varscan2
- IKBKE | c.1587G>A p.K529= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV65626281, COSV65627294; called by muse, mutect2, varscan2
- KCNH6 | c.1146G>T p.R382= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV59003840; called by muse, mutect2
- NCKAP5 | c.2922G>A p.L974= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV58458762; called by muse, mutect2
- NHSL2 | c.231C>T p.V77= (on ENST00000510661; = p.V443= on NM_001013627.2) | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs145938118, COSV101030276; called by muse, mutect2, varscan2
- NSMCE3 | c.555C>T p.L185= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs1455689224, COSV54278604; called by muse, mutect2, varscan2
- RRM2 | c.834A>G p.K278= | Silent (SNP) | VAF 61/283 reads (22%) | catalogued as COSV58817323; called by muse, mutect2, varscan2
- STK33 | c.1167G>A p.V389= | Silent (SNP) | VAF 80/382 reads (21%) | catalogued as COSV59405100; called by muse, mutect2, varscan2
- ZNF835 | c.693C>T p.F231= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV73379464; called by muse, mutect2
- C7orf66 | n.67G>C | RNA (SNP) | VAF 68/169 reads (40%) | called by muse, mutect2, varscan2
